Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7183, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7183-01A (Primary Tumor).

[page 1 of 2]
**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to [REDACTED] the section "SPECIMEN" may have been added. ****

DIAGNOSIS

- (A) TOTAL LARYNGECTOMY, LEFT SELECTIVE NECK DISSECTION LEVEL II, III, AND IV:
SQUAMOUS CARCINOMA, WELL-DIFFERENTIATED, INVOLVING LEFT TRANSGLOTTIC REGION.
THE TUMOR IS APPROXIMATELY 0.5 CM IN GREATEST THICKNESS AND 3.7 CM IN GREATEST DIMENSION.
No vascular invasion identified.
Margins of resection free of tumor.
No tumor present in 36 lymph nodes (0/17 Level II, 0/8 Level III, 0/11 Level IV).
Thyroid, no tumor present.

Entire report and diagnosis completed by: [REDACTED]

GROSS DESCRIPTION

- (A) TOTAL LARYNGECTOMY, LEFT SELECTIVE NECK DISSECTION LEVEL II, III, AND IV
- Overall 9.0 x 7.0 x 5.0 cm laryngectomy with hyoid bone, thyroid gland, strap muscle and left neck dissection level II, III and IV.
There is a 3.7 x 2.5 cm exophytic tumor in the left transglottic area. The tumor does not cross the midline anteriorly or posteriorly.
The left thyroid lobe is 4.5 x 3.0 x 1.5 cm. The right thyroid lobe is 2.5 x 2.0 x 1.0 cm. The right thyroid lobe has an irregular lateral edge. The thyroid gland is unremarkable. The tumor does not invade the anterior soft tissues.

INK CODE: Black - mucosal and tracheal margin.

SECTION CODE: A1, A2, tracheal margin, en face for frozen section diagnosis; A3-A6, right pharyngeal margin from 12-6 o'clock (anterior to posterior), en face; A7-A10, left pharyngeal margin from 6-12 o'clock (posterior to anterior, en face); A11-A27, entire tumor from right to left; A28-A30, one bisected lymph node in each; A31, two possible lymph nodes; A32-A34, four possible lymph nodes in each (A28-A34 are from level II); A35-A39, one lymph node bisected in each; A40, three possible lymph nodes (A35-A40 are from level III); A41, A42, one bisected lymph node in each; A43, four possible lymph nodes; A44, five possible lymph nodes; A41-A44 are from level IV; A45, right thyroid lobe; A46, left thyroid lobe.

*FS/DX: FSA, NO INVASIVE CARCINOMA AT MARGIN. [REDACTED]

SNOMED CODES

[page 2 of 2]
M-80703 T-24100

Source: NCI Genomic Data Commons file 55c068e8-9d79-409e-a7fd-deff462a198b (TCGA-CV-7183.36925A3F-4E0D-4775-B158-1D9E5B4AC20E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).